Somatic mutation profile of tumor specimen MP2PRT-PATULJ-TMP1-B (aliquot MP2PRT-PATULJ-TMP1-B-1-0-D-A835-36) from MP2PRT case MP2PRT-PATULJ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.5 years (906 days).
Specimen MP2PRT-PATULJ-TMP1-B: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 93a228b2-fc54-4354-82ee-12bcfb889a61.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATULJ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATULJ-NB1-A-1-0-D-A835-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8a39131d-6aeb-476c-b303-de93930f0d14

The open-access MAF lists 11 somatic variants for this specimen: 10 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 10, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 62/479 reads (13%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTPN11 | c.215C>T p.A72V | Missense Mutation (SNP) | VAF 50/542 reads (9%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.806); catalogued as rs121918454, CM013417, COSV61005613, COSV61008344, COSV61012146; ClinVar: likely pathogenic / conflicting interpretations of pathogenicity; called by muse, mutect2
- BSN | c.8504G>A p.R2835H | Missense Mutation (SNP) | VAF 68/621 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as rs147846190; called by muse, mutect2, varscan2
- FBXO10 | c.1312C>T p.R438W | Missense Mutation (SNP) | VAF 90/488 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as rs771838111, COSV52836153; called by muse, mutect2, varscan2
- FLT3 | c.1765T>G p.Y589D | Missense Mutation (SNP) | VAF 14/468 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); catalogued as COSV54069256, COSV54073406; called by muse, mutect2
- NCAM2 | c.2030C>T p.P677L | Missense Mutation (SNP) | VAF 100/699 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765685495, COSV53072800; called by muse, mutect2, varscan2
- PSD2 | c.415G>A p.A139T | Missense Mutation (SNP) | VAF 203/559 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.144); catalogued as rs893913392, COSV51197298; called by muse, mutect2, varscan2
- SHKBP1 | c.1114C>G p.P372A | Missense Mutation (SNP) | VAF 39/388 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.192); catalogued as COSV52540622; called by muse, mutect2, varscan2
- ZNF765 | c.227G>T p.R76I | Missense Mutation (SNP) | VAF 25/367 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as rs536715792; called by muse, mutect2
- DNAH9 | c.12169T>G p.F4057V | Missense Mutation (SNP) | VAF 69/781 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ZNF407 | c.4587C>T p.R1529= | Silent (SNP) | VAF 74/810 reads (9%) | catalogued as rs754835140, COSV55265783; called by muse, mutect2
